MMRF case MMRF_2386 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7bd4783d-8c72-484c-adc4-4b374d116e04

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.8 years (23,680 days); ISS stage: II; Days to last known disease status: 715 days (2.0 years); Days to last follow up: 715 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 210 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 197 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 341 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 341 days; Days to treatment end: 454 days (1.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 467 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 1): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 7.22 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.92 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.12 ×10⁹/L; Platelets 353 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Glucose 4.95 mmol/L; C-Reactive Protein 0.45 mg/dL.
- Day 78 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 77.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Hemoglobin 5.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.66 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 188 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 104 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Hemoglobin 5.7 mmol/L; Leukocytes 5.4 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.12 mmol/L.
- Day 267 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 35.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Hemoglobin 5.58 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.84 ×10⁹/L; Platelets 370 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 376 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 107 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Hemoglobin 5.46 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.66 ×10⁹/L; Platelets 397 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 454 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 73.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Hemoglobin 5.21 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.21 ×10⁹/L; Platelets 362 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 1.95 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 519: Hemoglobin 5.21 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 453 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.
- Day 610: Serum Free Immunoglobulin Light Chain, Kappa 15.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Hemoglobin 5.7 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.71 ×10⁹/L; Platelets 363 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 715: Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Hemoglobin 5.21 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.82 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -1: Weight: 87 kg; Height: 183 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2386_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2386_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
